Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6YT, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6YT-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

ICD-O-3
Fibromyosarcoma 8811/3
Site L Thigh NOS
C49.2
JJS 8/9/13

....

Clinical Diagnosis & History:

Increasing left thigh mass high grade, myxofibrosarcoma.

Specimens Submitted:

1: SP: Left posterior thigh mixfibrosarcoma

DIAGNOSIS:

1. SKIN AND SOFT TISSUE, LEFT POSTERIOR THIGH; EXCISION:
- HIGH GRADE MYXOFIBROSARCOMA, INVOLVING SUBCUTANEOUS TISSUE.
- TUMOR SIZE: 9.2 x 7.1 CM.
- UNREMARKABLE SKELETAL MUSCLE.
- THE MARGINS OF RESECTION ARE FREE OF TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and labeled "left posterior thigh myxofibrosarcoma, short stitch equals superior margin, long stitch lateral". The specimen consists of a 25.1 x 9.9 cm ellipse of tan wrinkled skin surfaced by a 4.3 cm linear scar. The underlying excised tissue consists of yellow-tan lobulated fat and red-brown skeletal muscle measuring 25.3 x 19.2 x 6.4 cm. A short stitch designates the superior margin and a long stitch designates the lateral margin. The specimen is oriented and inked as follows: superior blue, inferior red, anterior / deep black, posterior -- skin, medial yellow, and lateral green. Serial sectioning from medial to lateral reveals a 9.2 x 7.1 cm well-circumscribed tan gelatinous subcutaneous mass, abutting the posterior skin and 1.9 cm from the nearest deep margin. Tissue is submitted for TPS. The specimen is photographed and representatively submitted.

Summary of sections:

** Continued on next page **

[page 2 of 2]
SM superior margin
IM inferior margin
MM medial margin
LM lateral margin
AM anterior / deep margin
PM posterior / skin margin
T -- tumor

Page 2 of 2

Summary of Sections:

Part 1: SP: Left posterior thigh mixfibrosarcoma

Block	Sect. Site	PCs
2	AM	2
2	IM	2
2	LM	2
2	MM	2
2	PM	2
2	SM	2
4	T	4

** End of Report **

Source: NCI Genomic Data Commons file 692deddf-6b3f-46db-8afe-374c3c5dcdd6 (TCGA-DX-A6YT.0BC759DC-D2ED-40A9-83CA-CDDD22A51C0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).